Gene-level copy-number profile of tumor specimen TCGA-DS-A7WI-01A from TCGA case TCGA-DS-A7WI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 43.7 years (15,970 days).
Specimen TCGA-DS-A7WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e63bffae-0b91-4358-8a6e-460d5299db2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DS-A7WI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4f7d052-b64c-4e60-9ed5-c87dee6514a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 1,680; copy number 3: 1,583; copy number 4: 37,781; copy number 5: 9,920; copy number 6: 6,733; copy number 8: 1,970; copy number 9: 13; copy number 11: 11; copy number 17: 20; copy number 20: 31; copy number 21: 8; copy number 22: 11; copy number 32: 35; copy number 111: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DS-A7WI-01A-12D-A350-01): tumor purity 0.85, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 141 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,267,601–67,833,467, 13 genes, copy number 9 (within-gene range 6–9): RNU4ATAC4P, DNAJB6P4, IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P.
- chr7:53,187,388–56,106,476, 66 genes, copy number 17–32 (broad region; genes not listed).
- chr11:97,222,644–103,092,194, 62 genes, copy number 11–111 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
